CGCI case HTMCP-01-15-00370 — HIV+ Tumor Molecular Characterization Project - Diffuse Large B-Cell Lymphoma (CGCI-HTMCP-DLBCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/fdadda74-41ed-4ac2-aa97-0634c2d8863b

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 45 years; Vital status: Alive.

Diagnoses (1)
1. Diffuse large B-cell lymphoma, NOS: ICD-O-3 morphology code: 9680/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Liver; Classification of tumor: primary; Age at diagnosis: 45.6 years (16,648 days); Year of diagnosis: 2011; Method of diagnosis: Biopsy; Ann Arbor clinical stage: Stage IV; Ann Arbor pathologic stage: Stage IV; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 2,142 days (5.9 years); Ann Arbor extranodal involvement: Yes; Max tumor bulk site: Axillary lymph nodes; Sites of involvement: Liver.
   Pathology details: Additional pathology findings: Percent follicular component > 10%; Bone marrow malignant cells: No; Lymph node involved site: Axillary.
   Pathology details: Lymph node involved site: Cervical, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Pharmaceutical Therapy, NOS.

Follow-up (4 entries)
- Days to follow up: 0 days; ECOG performance status: 0.
- Days to follow up: 1,242 days (3.4 years); Disease response: Tumor Free.
- Days to follow up: 2,142 days (5.9 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: day -2,111.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL2: Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- BCL6: Positive; Specialized molecular test: BCL6 > 30%.
- CCND1: Negative.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD10: Positive; Specialized molecular test: CD10 > 30%.
- CD19: Positive.
- CD20 (IHC): Positive.
- CD20: Positive.
- CD23: Positive.
- CD3 (IHC): Negative.
- CD5: Negative.
- CD79A (IHC): Positive.
- IRF4 (IHC): Negative; Specialized molecular test: MUM1 > 30%.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC: Normal.
- TP53 (IHC): Positive; Specialized molecular test: P53 > 20%.
- Epstein-Barr Virus (ISH): Negative.
- Lactate Dehydrogenase 269 [Blood test normal range upper: 210].

Other clinical attributes
- Day -2,111: Risk factors: HIV/AIDS.
- Day -2,111: Comorbidities: HIV/AIDS.
- Day 0: Weight: 81.19 kg; Height: 167.64 cm; BMI: 28.9; CD4 count: 143; Haart treatment indicator: Yes; HIV viral load: 43627.
- Day 0: Comorbidities: Lymphocytic Meningitis.
- Day 0: Cdc hiv risk factors: Homosexual Contact.
- Day 0: Risk factors: Lymphocytic Meningitis.
- Day 1,242: Nadir CD4 count: 143.

Exposures
- Tobacco smoking status: Current Smoker.

Biospecimens (3 samples)
- Sample HTMCP-01-15-00370-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-01-15-00370-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample HTMCP-01-15-00370-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Diffuse large B-cell lymphoma (DLBCL) NOS (any anatomic site nodal or extranodal); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Tobacco smoking history indicator: 2; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- History of disease: Year of HIV diagnosis: 2005; Haart therapy prior to diagnosis: Yes; Haart therapy at diagnosis: No; Cdc HIV risk group: Homosexual or bisexual contact; History relevant infectious diagnosis: Lymphocytic Meningitis.
- Primary pathology: Follicular component percent: > 10%; Extranodal site involvement: 1; Method initial path diagnosis: Biopsy (all types).
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: cervical.
- Tests performed: LDH level: 269.
- Tests performed, Genetic testing results, Genetic testing result 1: Immunophenotypic analysis tested: CD19.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: BCL2.
- Tests performed, Genetic testing results, Genetic testing result 4: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 6: Immunophenotypic analysis tested: CD23.
- Tests performed, Genetic testing results, Genetic testing result 7: Immunophenotypic analysis tested: CD5.
- Tests performed, Genetic testing results, Genetic testing result 8: Immunophenotypic analysis tested: Cyclin D1.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 1: Genetic abnormality tested: C-myc.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 2: Genetic abnormality results: Gain.

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-DLBCL_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-01-15-00370-01A-01E-11869:
- % tumour top: 90
- % tumour bottom: 90

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-DLBCL_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-01-15-00370-01A-01S-11869:
- % tumour top: 90
- % tumour bottom: 90
